Somatic mutation profile of tumor specimen TARGET-30-PAUWYM-01A (aliquot TARGET-30-PAUWYM-01A-01D) from TARGET case TARGET-30-PAUWYM, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.7 years (621 days).
Specimen TARGET-30-PAUWYM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3be28a5a-ce22-4f6c-b1c0-d147996f7f45.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUWYM-10A (Blood Derived Normal), aliquot TARGET-30-PAUWYM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/790b9858-7fc1-4808-9fdb-c813604c2316

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.8550G>T p.K2850N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV55117929; called by muse, mutect2, varscan2
- COL6A3 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55117939; called by muse, mutect2, varscan2
- DNAH9 | c.7461G>T p.L2487= | Silent (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- RLIM | c.*2197G>T | 3'UTR (SNP) | VAF 50/152 reads (33%) | catalogued as COSV60329798; called by muse, mutect2, varscan2
- USP34 | c.5617+10C>A | Intron (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
